Somatic mutation profile of tumor specimen TCGA-RW-A68D-01A (aliquot TCGA-RW-A68D-01A-11D-A35D-08) from TCGA case TCGA-RW-A68D, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 31.3 years (11,438 days).
Specimen TCGA-RW-A68D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a58d80aa-aa26-4f1b-b461-f06b5a5e6948.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A68D-10A (Blood Derived Normal), aliquot TCGA-RW-A68D-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0da87218-3822-4aa5-98dc-92a94a2258d1

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPAS1 | c.1595A>G p.Y532C | Missense Mutation (SNP) | VAF 73/141 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55383831, COSV55385520; called by muse, mutect2, varscan2
- SLC35A4 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 44/100 reads (44%) | catalogued as COSV60052232; called by muse, mutect2, varscan2
- SQOR | c.52T>A p.C18S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs1335473160; called by muse, mutect2, varscan2
- CRAT | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2
- SLC30A5 | c.1241G>C p.S414T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CD300LG | c.369C>T p.F123= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs776427136, COSV53225012; called by muse, mutect2, varscan2
- IL16 | c.2079C>T p.H693= | Silent (SNP) | VAF 118/308 reads (38%) | called by muse, mutect2, varscan2
